Somatic mutation profile of tumor specimen TCGA-RR-A6KB-01A (aliquot TCGA-RR-A6KB-01A-12D-A33T-08) from TCGA case TCGA-RR-A6KB, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 51.2 years (18,713 days).
Specimen TCGA-RR-A6KB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb16e9b2-2445-4931-abd0-a04054d3a392.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RR-A6KB-10A (Blood Derived Normal), aliquot TCGA-RR-A6KB-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c24e2723-b3c7-4240-a19c-2c50b62c9a91

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 31, Silent 10, Splice Site 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 11/100 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.14045G>A p.R4682H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.193); catalogued as rs977034852, COSV100316751; called by muse, mutect2, varscan2
- ATP4A | c.2755T>A p.F919I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV99382443; called by muse, mutect2
- BPIFB1 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs201913573, COSV53609296; called by mutect2, varscan2
- CCT3 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99827243; called by muse, mutect2, varscan2
- CFL1 | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV100354031; called by muse, mutect2, varscan2
- CHST1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100346179; called by muse, mutect2, varscan2
- CTDP1 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50000260, COSV99311360; called by muse, mutect2, varscan2
- DHX30 | c.2543T>A p.V848E (on ENST00000445061 / NM_138615.3; = p.V809E on NM_014966.3) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99275083; called by muse, mutect2, varscan2
- EPB42 | c.631G>A p.V211M (on ENST00000441366 / NM_001114134.2; = p.V241M on NM_000119.3) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752892136, COSV55749838; called by muse, mutect2, varscan2
- FAM24B | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750572967, COSV59028181; called by muse, mutect2, varscan2
- GGT7 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs778546985, COSV60541309; called by muse, mutect2, varscan2
- GGTLC2 | c.304+1G>T p.X102_splice | Splice Site (SNP) | VAF 36/169 reads (21%) | catalogued as COSV101312210; called by muse, mutect2, varscan2
- GPR26 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs896088887, COSV99500850; called by muse, mutect2, varscan2
- HDHD3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs747271508, COSV53056680; called by muse, mutect2, varscan2
- HIPK1 | c.1024A>C p.S342R | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101060313; called by muse, mutect2, varscan2
- HPN | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 45/187 reads (24%) | catalogued as COSV99385018; called by muse, mutect2, varscan2
- IGSF11 | c.431C>T p.P144L (on ENST00000393775 / NM_001015887.3; = p.P143L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV100677220; called by muse, mutect2, varscan2
- MAGI3 | c.2247+3_2247+6del p.X749_splice | Splice Site (DEL) | VAF 12/94 reads (13%) | catalogued as rs780901997; called by mutect2, pindel
- NEB | c.19291C>T p.R6431W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs200804762, COSV99420162; called by muse, mutect2, varscan2
- OR10V1 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV100275781; called by muse, mutect2, varscan2
- P2RY14 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs145589776, COSV56385294; called by muse, mutect2, varscan2
- PCDHB16 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.194); catalogued as rs782406977, COSV53368876; called by muse, varscan2
- PCDHB4 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.009); catalogued as COSV99522076; called by muse, varscan2
- PKD1L1 | c.7714T>A p.Y2572N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV99219280; called by muse, mutect2, varscan2
- PLEKHG5 | c.1780G>A p.E594K (on ENST00000400915 / NM_001042663.3; = p.E557K on NM_020631.6) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs754429270, COSV61068093; called by muse, mutect2, varscan2
- PROKR2 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs753089596, COSV54086246, COSV99450151; called by muse, mutect2, varscan2
- PRPF40B | c.1459C>T p.R487* (on ENST00000380281; = p.R481* on NM_012272.3) | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as rs1416230045, COSV56060864; called by muse, mutect2, varscan2
- SCUBE1 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749908505, COSV62611258, COSV62612465; called by muse, mutect2, varscan2
- SPEG | c.2441-2A>T p.X814_splice | Splice Site (SNP) | VAF 26/133 reads (20%) | catalogued as COSV100404135; called by muse, mutect2, varscan2
- TMC5 | c.1927T>C p.Y643H (on ENST00000396229 / NM_001105248.1; = p.Y397H on NM_024780.5) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1009490882, COSV99572362; called by muse, mutect2, varscan2
- UGT1A3 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100530129; called by muse, mutect2
- VRK3 | c.1402A>G p.I468V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774654658, COSV100371526; called by muse, mutect2, varscan2
- IGHV6-1 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TRBV20-1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ABCA1 | c.930G>A p.G310= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV101036811; called by muse, mutect2
- ABI3 | c.324G>A p.E108= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99865452; called by muse, mutect2, varscan2
- CCDC185 | c.570G>A p.S190= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs774785214, COSV64820721; called by muse, mutect2, varscan2
- CYLC2 | c.891G>A p.T297= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1292325701, COSV66336210; called by muse, mutect2, varscan2
- E2F8 | c.480C>T p.I160= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs758702181, COSV100001429; called by muse, mutect2, varscan2
- EGF | c.2571T>C p.C857= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV99490765; called by muse, mutect2, varscan2
- FBLN2 | c.3324C>T p.P1108= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs770096274, COSV99851722; called by muse, mutect2, varscan2
- LGI3 | c.1590C>A p.P530= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV100102994; called by muse, mutect2, varscan2
- LRFN2 | c.1986C>T p.S662= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100599435; called by muse, mutect2, varscan2
- OPRD1 | c.876C>T p.R292= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV52382084; called by muse, mutect2
